Somatic mutation profile of tumor specimen TCGA-13-0791-01A (aliquot TCGA-13-0791-01A-01W-0371-08) from TCGA case TCGA-13-0791, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.5 years (21,380 days).
Specimen TCGA-13-0791-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f36c125-359b-4838-b66c-6692023a3b6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0791-10A (Blood Derived Normal), aliquot TCGA-13-0791-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/150c2ede-10b2-4262-8392-8f8d781cce9a

The open-access MAF lists 89 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Nonsense Mutation 4, RNA 2, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 42/46 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV100009100; called by muse, mutect2, varscan2
- ANAPC5 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV99946577; called by muse, mutect2, varscan2
- ANAPC5 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.519); catalogued as COSV99946580; called by muse, mutect2, varscan2
- ANO4 | c.1846G>A p.G616R (on ENST00000392977 / NM_001286615.2; = p.G581R on NM_178826.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781593105, COSV54610034, COSV54615989; called by muse, mutect2, varscan2
- ARHGAP35 | c.2983C>A p.L995M | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV101351903; called by muse, mutect2
- BBS9 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV54190866; called by muse, mutect2, varscan2
- CHRM2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 171/241 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs768531848, COSV57767335, COSV57769152; called by muse, mutect2, varscan2
- CHRM3 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs144239896; called by muse, mutect2, varscan2
- CNTNAP5 | c.3502G>A p.V1168I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375640846, CM1010519; called by muse, mutect2, varscan2
- COL4A2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV64635556; called by muse, mutect2, varscan2
- CPN2 | c.1402T>A p.W468R | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60472322; called by muse, mutect2, varscan2
- DCC | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 137/213 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as COSV59084715, COSV59142776; called by muse, mutect2, varscan2
- EDA | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs149975042, CM1513930, COSV58879427; called by muse, mutect2, varscan2
- EDARADD | c.491C>A p.T164N (on ENST00000334232 / NM_145861.4; = p.T154N on NM_080738.4) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100513230; called by muse, mutect2, varscan2
- EEF1D | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.384); catalogued as COSV57823314; called by muse, mutect2, varscan2
- FAT1 | c.4117G>A p.V1373I | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772458984, COSV71676289; called by muse, mutect2, varscan2
- FNDC1 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs773039427, COSV51941465; called by muse, mutect2, varscan2
- GCFC2 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 29/115 reads (25%) | catalogued as COSV58083813; called by muse, mutect2, varscan2
- GDNF | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 121/767 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427605; called by muse, mutect2, varscan2
- GNAT3 | c.965A>T p.H322L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68070362; called by muse, mutect2, varscan2
- GRIK3 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 50/549 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.427); catalogued as rs376333303; called by muse, mutect2
- GSE1 | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53674332; called by muse, mutect2, varscan2
- HTR1F | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60391527; called by muse, mutect2, varscan2
- ITGA2B | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs375195998; called by muse, mutect2, varscan2
- KCNA3 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV63900814; called by muse, mutect2, varscan2
- KCNE4 | c.544T>G p.S182A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.561); catalogued as COSV56055519; called by muse, mutect2, varscan2
- LAMP2 | c.556+1G>T p.X186_splice | Splice Site (SNP) | VAF 94/245 reads (38%) | catalogued as COSV52355794; called by muse, mutect2, varscan2
- MEF2D | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61730671; called by muse, mutect2, varscan2
- MPP6 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.597); catalogued as COSV99757969; called by muse, mutect2
- MTF1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs778456735, COSV65990855; called by muse, mutect2, varscan2
- MTMR1 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1486439252, COSV64892436; called by muse, mutect2, varscan2
- MYH4 | c.5122C>G p.Q1708E | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.393); catalogued as COSV55116309, COSV55127815; called by muse, mutect2, varscan2
- MYO18B | c.7202A>G p.K2401R | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as COSV59149593; called by muse, mutect2, varscan2
- NEK10 | c.2944G>C p.E982Q | Missense Mutation (SNP) | VAF 90/189 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as COSV55366568; called by muse, mutect2, varscan2
- NRXN1 | c.3542A>T p.H1181L | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV58476299, COSV58500462; called by muse, mutect2, varscan2
- NUFIP2 | c.1246A>G p.N416D | Missense Mutation (SNP) | VAF 68/71 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV56606680; called by muse, mutect2, varscan2
- NUMB | c.1897C>T p.P633S (on ENST00000355058; = p.P622S on NM_003744.5) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as rs1282263831, COSV99390597; called by muse, mutect2, varscan2
- OCA2 | c.2497G>T p.V833L | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs200396611, CM130468, COSV62342651, COSV62359803; called by muse, mutect2, varscan2
- PKD2L1 | c.1171C>A p.L391M | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.196); catalogued as COSV58399445; called by muse, mutect2, varscan2
- RBL1 | c.1842G>A p.M614I | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100727344; called by muse, varscan2
- RNF145 | c.502A>G p.I168V (on ENST00000424310 / NM_001199383.2; = p.I196V on NM_144726.2) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV50875283; called by muse, mutect2, varscan2
- RTP5 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as rs1392043686, COSV58322364; called by muse, mutect2, varscan2
- SLC12A1 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV57712471; called by muse, mutect2, varscan2
- SPATS2L | c.407T>A p.I136K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.227); catalogued as COSV62354273; called by muse, mutect2, varscan2
- STK32B | c.143T>C p.M48T | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776205066, COSV99287821; called by muse, mutect2, varscan2
- SV2A | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64966178; called by muse, mutect2, varscan2
- TAAR6 | c.761G>T p.R254I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51582673, COSV51582846; called by muse, mutect2, varscan2
- TAF1 | c.1355A>G p.N452S (on ENST00000373790 / NM_138923.4; = p.N473S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99337357; called by muse, mutect2
- TAS2R14 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV101115900; called by muse, mutect2, varscan2
- TCHH | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV64277872, COSV64278259; called by muse, mutect2, varscan2
- TGFBR2 | c.1402A>C p.K468Q | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55462287; called by muse, mutect2, varscan2
- TLR5 | c.324C>A p.Y108* | Nonsense Mutation (SNP) | VAF 29/207 reads (14%) | catalogued as COSV60561196; called by muse, mutect2, varscan2
- TLR6 | c.1112A>G p.E371G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV67935902; called by muse, mutect2, varscan2
- TMEM236 | c.359A>T p.D120V | Missense Mutation (SNP) | VAF 419/1010 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs888271639; called by muse, mutect2, varscan2
- WDR13 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV54333913; called by muse, mutect2, varscan2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF135 | c.1538A>T p.Q513L (on ENST00000313434 / NM_001289401.2; = p.Q525L on NM_003436.4) | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV100536993; called by muse, varscan2
- ZNF354C | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100203853; called by muse, mutect2
- ZNF354C | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59610203; called by muse, mutect2, varscan2
- ZNF471 | c.627T>A p.N209K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV57292696; called by mutect2, varscan2
- ZNF599 | c.1700A>G p.E567G | Missense Mutation (SNP) | VAF 175/340 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV61397739; called by muse, mutect2, varscan2
- ZNF683 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV62876142; called by muse, mutect2, varscan2
- ZNF75D | c.1440C>G p.S480R | Missense Mutation (SNP) | VAF 111/459 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV100883709; called by muse, mutect2, varscan2
- ZNF799 | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV70123591; called by muse, mutect2, varscan2
- CDK12 | c.363_365delinsA p.D121Efs*5 | Frame Shift Del (DEL) | VAF 58/62 reads (94%) | called by pindel, varscan2*
- SZT2 | c.1166A>G p.K389R | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); called by muse, mutect2
- TOP2A | c.602_605dup p.E203Wfs*2 | Frame Shift Ins (INS) | VAF 220/366 reads (60%) | called by pindel, varscan2
- ADNP2 | c.2748C>T p.I916= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV51542925; called by muse, mutect2, varscan2
- APOB | c.6585A>G p.K2195= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV51956496; called by muse, mutect2, varscan2
- ATP9B | c.1416C>A p.T472= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs373609399, COSV56963706; called by muse, mutect2, varscan2
- ATXN3L | c.438A>C p.T146= | Silent (SNP) | VAF 76/134 reads (57%) | catalogued as COSV66076351; called by muse, mutect2, varscan2
- BAZ2B | c.1770A>G p.Q590= | Silent (SNP) | VAF 46/361 reads (13%) | catalogued as COSV100601149; called by muse, mutect2, varscan2
- CEACAM6 | c.558G>A p.P186= | Silent (SNP) | VAF 241/467 reads (52%) | catalogued as rs781933343, COSV52266965, COSV52269689; called by muse, mutect2, varscan2
- CHMP5 | c.186G>A p.K62= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV56304077; called by muse, mutect2, varscan2
- CYP11A1 | c.798T>C p.H266= | Silent (SNP) | VAF 362/723 reads (50%) | catalogued as rs768914878, COSV51435385; called by muse, mutect2, varscan2
- DCAF8L1 | c.1287G>A p.K429= | Silent (SNP) | VAF 57/195 reads (29%) | catalogued as COSV71595211; called by muse, mutect2, varscan2
- ITIH1 | c.2055C>T p.T685= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV56259169; called by muse, mutect2, varscan2
- KBTBD12 | c.1671C>T p.C557= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs754622452, COSV59682364; called by muse, mutect2, varscan2
- KCNJ8 | c.468C>T p.I156= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV99557765; called by muse, mutect2
- OR5K2 | c.438A>T p.T146= | Silent (SNP) | VAF 84/248 reads (34%) | catalogued as COSV71143571; called by muse, mutect2, varscan2
- PCDHB9 | c.1524G>C p.A508= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs782814595, COSV53379630, COSV53384818; called by muse, mutect2, varscan2
- PELI1 | c.1071C>T p.A357= | Silent (SNP) | VAF 105/306 reads (34%) | catalogued as rs190570686; called by muse, mutect2, varscan2
- PITPNM2 | c.3276G>A p.T1092= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs151113446; called by muse, mutect2, varscan2
- SETD5 | c.3174G>A p.Q1058= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV56718260; called by muse, mutect2, varscan2
- SULT1A1 | c.723C>T p.T241= | Silent (SNP) | VAF 67/237 reads (28%) | catalogued as COSV100132115; called by muse, mutect2, varscan2
- GLOD4 | chr17:782596 A>G | 5'Flank (SNP) | VAF 9/13 reads (69%) | catalogued as rs368602188; called by muse, mutect2, varscan2
- LINC02843 | n.384G>A | RNA (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- SNORD116-20 | n.89G>T | RNA (SNP) | VAF 248/644 reads (39%) | catalogued as rs755954197; called by muse, mutect2, varscan2
